Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A2LT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A2LT-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Address:

Gender: F

DOB: [REDACTED] (Age: [REDACTED])

Service: Gynecology

Location: OTHER

MRN:

Hospital #:

Patient Type:

Accession #

Taken:

Received:

Reported:

Physician(s): [REDACTED] M.D.

1CD-0-3

DIAGNOSIS:

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION
- NO EVIDENCE OF MALIGNANCY (4/4)

LYMPH NODES, LEFT OBTURATOR, EXCISION
- NO EVIDENCE OF MALIGNANCY (3/3)

LYMPH NODES, RIGHT PELVIC, EXCISION
- NO EVIDENCE OF MALIGNANCY (13/13)

LYMPH NODES, RIGHT COMMON/PERIAORTIC, EXCISION
- NO EVIDENCE OF MALIGNANCY (2/2)

LYMPH NODES, LEFT COMMON/PERIAORTIC, EXCISION
- NO EVIDENCE OF MALIGNANCY (3/3)

UTERUS, HYSTERECTOMY

- SQUAMOUS CELL CARCINOMA OF THE CERVIX, POORLY DIFFERENTIATED, INVASIVE TO A MAXIMUM DEPTH OF 1.2 CM (CERVIX THICKNESS OF 1.3 CM), EXTENDING INTO STROMA OF THE LOW UTERINE SEGMENT, RESECTION MARGINS NOT INVOLVED
- PROLIFERATIVE ENDOMETRIUM
- SIX PARAMETRIAL LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (6/6)

carcinoma, squamous cell, keratinizing, NOS
8071/3
Site: cervix, NOS 653.9
lw 8/18/11

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By

M.D.***

Intraoperative Consultation:

FS1: Lymph node, left obturator, excision

- "No carcinoma seen." by

[page 2 of 3]
Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a 60 year old woman with cervical carcinoma. Operative procedure: Pelvic lymph node dissection, radical hysterectomy.

Specimen(s) Received:

- A: LEFT EXTERNAL ILIAC LYMPH NODE
- B: LEFT OBTURATOR
- C: RIGHT PELVIC LYMPH NODE
- D: RIGHT COMMON / PERIAORTIC LYMPH NODE
- E: LEFT COMMON / PERIAORTIC LYMPH NODE
- F: HYSTERECTOMY, UTERUS, CERVIX

Gross Description

Received are six formalin-filled containers, each labeled with the patient's name. The first container is labeled "left exterior iliac." It contains multiple fragments of lobulated, yellow tan adipose tissue, measuring in aggregate 4 x 2.5 x 1 cm. Multiple lymph nodes are dissected from the fat, ranging from 0.4 and 1.5 cm in greatest dimension. Cut sections are light tan and unremarkable. Labeled A1, A2. Jar 1.

The second container is labeled "left obturator." It contains a white cassette labeled "FS1" which holds multiple fragments of yellow-tan soft tissue, measuring 2 x 1.7 x 0.3 cm. Labeled B1 (FS1). Also present in the container are multiple fragments of lobulated yellow-tan adipose tissue, measuring in aggregate 3 x 2.5 x 0.5 cm. Three putative lymph nodes are dissected, ranging from 0.3 and 1.5 cm in greatest dimension. Labeled B2. Jar 1.

The third container is labeled "right pelvic lymph node." It contains multiple fragments of lobulated yellow-tan adipose tissue, measuring in aggregate 4.5 x 4.5 x 1.5 cm. Several lymph nodes are dissected from the fat, ranging from 0.5 and 3.5 cm in greatest dimension. They appear unremarkable. Labeled C1-C3. Jar 1.

The fourth container is labeled "left common periaortic lymph node." It contains multiple fragments of lobulated yellow-tan adipose tissue, measuring in aggregate 2.5 x 1 x 0.5 cm. Two putative lymph nodes are identified. They measure 0.5 and 0.7 cm in greatest dimension. They appear unremarkable. Labeled D1. Jar 1.

The fifth container is labeled "right common periaortic lymph node." It contains one fragment of lobulated yellow-tan adipose tissue, measuring in aggregate 2.5 x 1 x 0.3 cm. Two putative lymph nodes are dissected, measuring 0.2 and 0.5 cm in greatest dimension. Labeled E1. Jar 1.

The sixth container is labeled "uterus and cervix." It contains a uterus with attached cervix weighing 83.4 gram and measuring 8 x 5 x 3.5 cm. The external os measures 2 cm in diameter. The serosal surface is tan pink and unremarkable. On opening, the cervical canal is ulcerated in an area measuring 1.9 x 1.5 x 1 cm. This area is surrounded by a tan firm area measuring 2.5 x 1 x 1 cm. The endometrial cavity measures 2.5 x 1.2 cm and the endometrium measures 0.1 cm in thickness. The myometrium measures up to 1.2 cm in maximal thickness. Labeled F1, F2 - serial left cervix with parametrium; F3, F4 - anterior right cervix with parametrium soft tissue; F5, F6 - anterior cervix with ectocervix; F7, F8 - cervix with lower uterine segment of the anterior uterus; F9 - anterior endometrium; F10, F11 - right posterior cervix with parametrium; F12, F13 - left cervix with parametrium; F14, F15 - posterior cervix with ectocervix; F16 - posterior cervix with lower uterine segment. Jar 2.

M.D.

Synopsis

SYNOPTIC REPORTING FORM FOR UTERINE CERVICAL NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Squamous cell (epidermoid) carcinoma, invasive type
Keratinizing subtype

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

3. The MAXIMUM DEPTH OF TUMOR INVASION is 12 mm.
4. The BREADTH (MAXIMUM HORIZONTAL DIMENSION) OF THE TUMOR is 25 mm.
5. The TOTAL THICKNESS OF THE CERVIX is 13 mm.
6. Lymphatic invasion by tumor IS identified but is FOCAL.
7. The NUCLEAR GRADE of the tumor is:
3 (Poorly-differentiated)
8. The tumor DOES NOT invade through the entire thickness of the cervix to involve contiguous parametrial tissues.
9. The tumor DOES NOT involve the uterine corpus.
10. The tumor DOES NOT involve the vagina.
11. Metastasis to regional lymph nodes is ABSENT.
12. The total number of metastatically-involved nodes is 0.
13. The total number of regional nodes examined is 31.
14. Extracapsular extension of metastatic tumor through the lymph node capsule is NOT APPLICABLE; NO METASTASIS IS SEEN.

15. DETAILED STAGING INFORMATION:

A. TUMOR GROWTH: THE PRIMARY NEOPLASM IS CLASSIFIED AS:

TNM SCHEME	FIGO SCHEME	DEFINITION
T1b	IB	Tumor confined to uterus but larger than T1a2/IA2

B. REGIONAL LYMPH NODES are classified as:

N0 (Regional nodes are NOT involved by metastasis)

C. DISTANT METASTASES: The status of distant tissues is:

M0 (Distant metastases are reportedly absent)

16. THE FINAL STAGE OF THE TUMOR IS:

AJCC SCHEME	FIGO SCHEME
1b	IB

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

This Surgical Pathology report is available on-line on

The performance characteristics of all immunohistochemical stains listed in this report (if any) were determined by the Diagnostic Immunohistochemistry

drawn from the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88). Some of these tests rely on the use of "in-house specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Health Care Financing Administration as a high complexity laboratory under CLIA '88. These tests need not be cleared or approved by the FDA prior to their use. Nevertheless, Federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report.

This test was developed and its performance characteristics determined by the Diagnostic Immunohistochemistry Laboratory at Barnes-Jewish Hospital. It has not been cleared or approved by the U.S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 8d352d99-774e-40d7-be1f-d43ec5c750e4 (TCGA-C5-A2LT.C9125C3D-81F0-4E3A-93BB-E2DD191B0B78.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).